Somatic mutation profile of tumor specimen TARGET-30-PASXRJ-01A (aliquot TARGET-30-PASXRJ-01A-01D) from TARGET case TARGET-30-PASXRJ, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.6 years (583 days).
Specimen TARGET-30-PASXRJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53e3c3b8-407e-4589-a514-6fde0ce670c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASXRJ-10A (Blood Derived Normal), aliquot TARGET-30-PASXRJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6379e046-9d1a-42a8-9ef7-f034d1334801

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGLV1-47 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs556936347; called by muse, mutect2, varscan2
- SMOX | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as COSV53869161; called by muse, mutect2, varscan2
- ADAMTS20 | c.144C>T p.V48= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs781460004, COSV67140932; called by muse, mutect2, varscan2
- SIGLEC8 | c.840C>A p.R280= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV58476213; called by muse, mutect2, varscan2
- TMED4 | c.276G>A p.R92= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- ZDBF2 | c.5757T>C p.R1919= | Silent (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
